Somatic mutation profile of tumor specimen MMRF_1539_2_BM_CD138pos (aliquot MMRF_1539_2_BM_CD138pos_T1_KHS5U_L08712) from MMRF case MMRF_1539, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.5 years (20,993 days).
Specimen MMRF_1539_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39193dac-df80-46d1-bcc7-41031f99fa0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1539_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1539_1_PB_Whole_C2_KBS5U_L03511; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f06c310d-bd2a-4dfa-9020-a78d0a64967b

The open-access MAF lists 82 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 18, Silent 16, Intron 10, Nonsense Mutation 2, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PDHA1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs794729213, CM000553, CM013279, COSV63328534; ClinVar: pathogenic; called by mutect2, varscan2
- AGTPBP1 | c.2678C>T p.T893I (on ENST00000357081 / NM_001330701.2; = p.T853I on NM_015239.2) | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61268110; called by muse, mutect2, varscan2
- DLGAP2 | c.1038C>A p.N346K | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV70101021; called by muse, mutect2, varscan2
- HSPA12A | c.1856A>T p.K619M | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV65020620; called by muse, mutect2, varscan2
- IGHD6-25 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 84/192 reads (44%) | catalogued as rs577590165; called by muse, varscan2
- IGLV3-25 | c.149A>C p.Y50S | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as rs373673041; called by muse, mutect2, varscan2
- MAMDC2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774754440; called by muse, mutect2, varscan2
- MLC1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.176); catalogued as rs529062080; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- PIK3C2G | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs1325391397; called by muse, mutect2, varscan2
- SIAE | c.651C>G p.S217R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs901413096; called by muse, mutect2, varscan2
- SNAI3 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs746301482; called by muse, mutect2, varscan2
- AADAC | c.929A>T p.K310I | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADGRL3 | c.2431G>T p.V811L (on ENST00000506720 / NM_001322402.2; = p.V743L on NM_015236.6) | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKH | c.1003T>A p.S335T | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- APBA2 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CACNB3 | c.991-2A>G p.X331_splice | Splice Site (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- GLRB | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- GNAS | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 61/208 reads (29%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.-134-1G>C | Splice Site (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- IRX4 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLK11 | c.236G>A p.C79Y (on ENST00000594768 / NM_144947.3; = p.C47Y on NM_006853.3) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTIF2 | c.104A>C p.H35P | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEURL4 | c.3796G>T p.G1266W | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8K1 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2
- PCDHAC2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- PEX6 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIK3C2G | c.3111G>T p.K1037N (on ENST00000676171; = p.K996N on NM_004570.5) | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RAD51B | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2
- RANBP2 | c.8938A>G p.K2980E | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SALL3 | c.2174A>C p.H725P | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- SARS1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TENT2 | c.545C>G p.T182R | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM39A | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA5A | c.642C>T p.P214= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- FRAS1 | c.10401T>C p.S3467= | Silent (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- FREM2 | c.675C>T p.G225= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV54831126; called by muse, mutect2, varscan2
- FREM2 | c.1488T>G p.G496= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- GAL3ST1 | c.222G>A p.P74= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as COSV58892434; called by muse, mutect2, varscan2
- GRM4 | c.576C>T p.Y192= | Silent (SNP) | VAF 58/258 reads (22%) | catalogued as rs368672368; called by muse, mutect2, varscan2
- KSR2 | c.1050C>T p.N350= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- NEK11 | c.351C>T p.D117= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs148912275; called by mutect2, varscan2
- PADI2 | c.1734C>T p.D578= | Silent (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- PIGA | c.561T>G p.T187= | Silent (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2, varscan2
- SEC16B | c.2613C>T p.S871= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as rs373528898; called by muse, mutect2
- SMR3B | c.45G>A p.A15= | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as rs200141400, COSV100513317; called by muse, mutect2, varscan2
- TRIOBP | c.531G>A p.R177= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1175605559; called by muse, mutect2
- VNN1 | c.1524A>G p.V508= | Silent (SNP) | VAF 25/120 reads (21%) | called by muse, varscan2
- ZNF568 | c.1842T>C p.T614= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as rs937222884; called by muse, mutect2, varscan2
- ZNF600 | c.444A>G p.L148= | Silent (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- ACTN4 | c.*401T>C | 3'UTR (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.*710A>C | 3'UTR (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- ADCY5 | c.*1841C>T | 3'UTR (SNP) | VAF 11/175 reads (6%) | catalogued as rs568114967; called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 11/82 reads (13%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- ANKRD17 | c.*767T>G | 3'UTR (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- COLEC11 | c.130+1625G>A | Intron (SNP) | VAF 58/340 reads (17%) | called by muse, mutect2, varscan2
- CTRB2 | c.53-91A>G | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2
- DNAJB2 | c.65+30T>G | Intron (SNP) | VAF 73/346 reads (21%) | called by muse, mutect2, varscan2
- EDN3 | chr20:59300543 T>C | 5'Flank (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- ETV1 | c.1110+26A>C | Intron (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- FAM131B | chr7:143353540 T>A | 3'Flank (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- GAB2 | c.*2936G>A | 3'UTR (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- GALNT1 | c.*1418G>A | 3'UTR (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- IRX3 | c.*66A>G | 3'UTR (SNP) | VAF 20/400 reads (5%) | called by muse, mutect2
- KIRREL3 | c.55+5315C>G | Intron (SNP) | VAF 34/219 reads (16%) | catalogued as COSV73106171; called by muse, mutect2, varscan2
- KLF4 | c.*243G>A | 3'UTR (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- MTREX | c.3077-854C>G | Intron (SNP) | VAF 22/92 reads (24%) | catalogued as rs1023515612; called by muse, mutect2, varscan2
- MYOM3 | c.3423+453G>A | Intron (SNP) | VAF 22/73 reads (30%) | catalogued as rs980876671; called by muse, mutect2, varscan2
- NKAPD1 | c.*227_*228del | 3'UTR (DEL) | VAF 7/69 reads (10%) | catalogued as rs1491340302; called by pindel, varscan2
- NTRK2 | c.1397-54969T>A | Intron (SNP) | VAF 30/116 reads (26%) | catalogued as rs1253883193; called by muse, mutect2, varscan2
- PI15 | c.*2451dup | 3'UTR (INS) | VAF 18/62 reads (29%) | called by mutect2, varscan2
- PPP1R1C | c.241+75A>G | Intron (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2, varscan2
- PSEN1 | c.*2315A>T | 3'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as COSV56196388; called by muse, mutect2, varscan2
- SBSPON | c.*2553T>C | 3'UTR (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- SLC17A4 | c.*1360G>A | 3'UTR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- SYK | c.*167T>C | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- TMEM225B | c.*76C>G | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- UHMK1 | c.*185G>T | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- USP4 | c.*405A>G | 3'UTR (SNP) | VAF 53/262 reads (20%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1878A>G | 3'UTR (SNP) | VAF 49/182 reads (27%) | called by muse, mutect2, varscan2
